Surgical pathology report (de-identified scan), TCGA case TCGA-38-4628, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site UNC, specimen TCGA-38-4628-01A (Primary Tumor).

[page 1 of 2]
Diagnosis:

- Lymph node, right hilar (R10), biopsy.
- One lymph node, negative for carcinoma.
- Hyalinized granulomata.

B: Lung, right upper lobe, lobectomy.

- Invasive moderately differentiated adenocarcinoma.
- Metastatic adenocarcinoma involving 1 (of 4) hilar lymph node.
- Hyalinized and partially calcified granulomata involving hilar lymph nodes and pulmonary parenchyma.

C: Lymph nodes, R4, biopsy.

- Multiple (2) lymph nodes, negative for carcinoma.
- Hyalinized granulomata.

D: Lymph node, right mainstem bronchus, biopsy.

- One lymph node, negative for carcinoma.
- Hyalinized granulomata.

E: Lymph node, R9, biopsy.

- One lymph node, negative for carcinoma.

F: Lymph node, station 7, biopsy.

- One lymph node, negative for carcinoma.

Comment:

See light microscopy template for additional prognostic and staging information.

Intraoperative Consultation:

A frozen section consultation was requested by Dr.

FSA1: Lymph node, right hilar (R10), biopsy

- Lymph node with anthracotic pigment, no neoplasm identified

B1: Right upper lobe mass, lobectomy

- Non-small cell carcinoma

FSB2: Bronchial margin, right upper lobectomy

- No neoplasm identified

Clinical History:

The patient has a right upper lobe mass.

Gross Description:

Received are six appropriately labeled containers.

Container A: Received fresh for frozen section is a 1.5 x 1.0 x 0.5 cm dark red soft tissue fragment which is bisected. One half was previously frozen as FSA1 and is submitted in block FSA1. The remainder of the tissue is submitted in block A1.

Container B is additionally labeled "RUL."

Specimen fixation: formalin

Type of specimen/parts of lung received: right upper lobectomy

Size of specimen: approximately 12.8 x 9.7 x 2.0 cm

Weight of specimen: 130.5 grams

Other attached structures: none

Tumor location: central-near bronchial margin

Tumor size: 3.5 x 2.4 x 2.3 cm

Relationship of tumor to bronchus: does not grossly appear to involve bronchus, however, it appears to be growing around the bronchus

Distance of tumor to bronchial margin: 0.3 cm

Relationship/distance of tumor to pleura: not invading the pleura, 0.2 cm

[page 2 of 2]
Distance of tumor to other surgical margins:

Presence/absence of satellite tumor nodules: Present, two small pleural nodules are identified; one is 0.4 cm in diameter and is approximately 5.2 cm from the main tumor mass. The second mass is 4 cm in diameter and is 3.1 cm from the main tumor mass.

Involvement of attached structures by tumor: not identified

Description of nontumorous lung: Sectioning the remainder of the lung exhibits soft, spongy, red aerated lung parenchyma with possible post-obstructive changes.

Comment: The bronchial margin was inked black along with a staple line. The bronchial margin was previously frozen. A portion of the tumor was given to Tissue Procurement (3 x 2.8 x 2.3 cm). A portion of the mass was previously frozen as FSB1 and is submitted in block FSB1. The bronchial margin was previously frozen as FSB2 and is submitted in block FSB2.

Block Summary:

B1 - additional bronchial margin (superseded by frozen section)
B2 - bronchial lymph node candidate
B3 - tumor and bronchus
B4 - tumor and adjacent lung
B5 - tumor and pleura
B6 - nodule closest to main tumor mass, bisected
B7 - nodule furthest from main tumor mass, bisected
B8 - representative lung with possible post-obstructive changes
B9 - uninvolved lung

Container C is additionally labeled "R4." It holds a 1.0 x 0.6 x 0.5 cm aggregate of two fragments of red/gray tissue. [REDACTED]

Container D is additionally labeled "mainstem bronchus lymph node." It holds a 1.0 x 0.5 x 0.4 cm fragment of dark gray tissue. [REDACTED]

Container E is additionally labeled "R9." It holds a 0.8 x 0.5 x 0.3 cm fragment of gray/tan tissue. [REDACTED]

Container F is additionally labeled "station 7." It holds a 1.5 x 0.5 x 0.2 cm fragment of dark gray/brown soft tissue. [REDACTED]

Light Microscopy:

Light microscopic examination is performed by Dr.

(Specimen B)

Tumor histologic type (WHO classification): adenocarcinoma

Tumor histologic grade (WHO classification): moderately differentiated

Tumor size (greatest dimension): 3.5 cm

Histologic assessment of surgical margins: surgical margins, including bronchial resection margin, appear negative for carcinoma

Pleural involvement: negative for carcinoma

In situ carcinoma: not identified

Invasion:

angiolymphatic - not identified

perineural - present

Lymph nodes (by node group): - Metastatic adenocarcinoma involving 1 (of 5) hilar lymph node.
- Multiple (2, R4; 1, right mainstem bronchus; 1, R9; 1, station 7) lymph nodes, negative for carcinoma.

Extracapsular extension of tumor in lymph nodes: not identified

Findings in nontumorous lung: hyalinized granulomata

Source: NCI Genomic Data Commons file ddc77d51-6a7d-4af8-81df-b3f4c6ab3b40 (TCGA-38-4628.0A4269D2-D168-4750-AB8C-3C27907C45EF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).